Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A00H, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A00H-01A (Primary Tumor).

Sample ID #:

Diagnosis:

Resectate of a portion of the large intestine, or rectosigmoid colon, with an ulcerated rectal carcinoma conforming to the histological type of a moderately differentiated colorectal adenocarcinoma, extending no closer than 4.5 cm to the aboral resection margin and circularly occupying the intestinal wall over a length of 5.5 cm. Invasive spread of tumor within all layers of the intestinal wall, as far as into the neighboring periproctic fatty tissue.

Oral and aboral resection margins and resection margin of the periproctic fatty tissue tumor-free.

Thirty-two regional lymph nodes tumor-free with uncharacteristic reactive changes.

Tumor stage therefore pT3 pN0 (0/32) L0 V0; G2 R0.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: rectum C20.9 per 3/31/11

Source: NCI Genomic Data Commons file 673505e9-d40b-412f-9c30-32f3749e7879 (TCGA-AG-A00H.DF3B5B10-1913-41AE-9B22-FD8E9AA3CBC1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).